MMRF case MMRF_1256 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f1b12b03-6135-40a1-9aef-0a600e3b5b9a

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.4 years (20,233 days); ISS stage: I; Days to last known disease status: 1,555 days (4.3 years); Days to last follow up: 1,555 days (4.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 172 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 206 days; Days to treatment end: 488 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 506 days (1.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -16 (ECOG 0): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 35.2 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 5.05 ×10⁹/L; Absolute Neutrophil 2.35 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 7.8 g/dL; Glucose 6.22 mmol/L.
- Day 54 (ECOG 0): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.267 mg/dL; Immunoglobulin G 22.5 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.1 µg/mL; Hemoglobin 6.08 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 4.73 mmol/L.
- Day 178 (ECOG 0): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.276 mg/dL; Immunoglobulin G 21.4 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 5.34 mmol/L.
- Day 246 (ECOG 0): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.274 mg/dL; Immunoglobulin G 17.7 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1 µg/mL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 304 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 7.04 mmol/L.
- Day 332 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.592 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 0.9 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 5.61 mmol/L.
- Day 424 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.581 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.5 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 5.06 mmol/L.
- Day 506 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.937 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.529 mg/dL; Immunoglobulin G 7.53 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1 µg/mL; Hemoglobin 7.75 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.5 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 6.16 mmol/L.
- Day 626 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.788 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.1 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 6.93 mmol/L.
- Day 687: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.4 µg/mL; Hemoglobin 7.32 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 4.68 mmol/L.
- Day 744: Hemoglobin 7.56 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.5 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 7.15 mmol/L.
- Day 915 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 9.68 g/L; Immunoglobulin A 2.04 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 5.17 mmol/L.
- Day 1,006 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 2.12 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.3 µg/mL; Hemoglobin 7.56 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 5.94 mmol/L.
- Day 1,083: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 2.18 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 4.68 mmol/L.
- Day 1,174 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 2.38 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 299 ×10⁹/L.
- Day 1,263: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 2.29 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.4 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.39 mmol/L.
- Day 1,362: M Protein 0.5 g/dL; Immunoglobulin G 9.9 g/L; Immunoglobulin A 2.34 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.3 µg/mL; Hemoglobin 6.63 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 4.9 mmol/L.
- Day 1,474 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 9 g/L; Immunoglobulin A 2.2 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 1.3 µg/mL; Hemoglobin 7.25 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 4.62 mmol/L.
- Day 1,555 (ECOG 0): M Protein 0.4 g/dL; Immunoglobulin G 7.99 g/L; Immunoglobulin A 1.85 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -16: Weight: 101 kg; Height: 149 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (1 sample)
- Sample MMRF_1256_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 178 days.
